CPTAC case C3N-03877 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ac8ce1f4-d475-4da0-89cb-30067c2a37d6

Demographics
Sex at birth: male; Race: asian; Year of birth: 1964; Vital status: Dead; Days to death: 745 days (2.0 years); Year of death: 2020; Country of birth: China.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 53.9 years (19,674 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 745 days (2.0 years); Progression or recurrence: no; Days to last follow up: 682 days (1.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7 cm (a second GDC size field records 6 cm); Lymph node involvement: Positive; Lymph nodes positive: 25; Lymph nodes tested: 35; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 275 days; Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 682 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 0.
- Days to follow up: 682 days (1.9 years); Disease response: Complete Response; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 682 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 2.

Other clinical attributes
- Weight: 88 kg; Height: 183 cm; BMI: 26.28; DLCO (% of predicted): 78; FEV1 before bronchodilator (% of reference): 70.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 30; Cigarettes per day: 20; Tobacco smoking onset year: 1987; Exposure duration years: 35.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03877-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 48 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03877-21: Section location: Right Lower Lobe; Percent tumor nuclei: 70; Percent necrosis: 20.
- Sample C3N-03877-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 78 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03877-22: Section location: Right Lower Lobe; Percent tumor nuclei: 55; Percent necrosis: 5.
- Sample C3N-03877-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 255 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 12 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03877-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
